Gene-level copy-number profile of tumor specimen ALCH-B1XB-TTP1-A from ALCHEMIST case ALCH-B1XB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 57.3 years (20,930 days).
Specimen ALCH-B1XB-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c60bbf1c-2fa1-4efd-baf5-6f44c71eba5d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1XB-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,730 have no estimate.
https://portal.gdc.cancer.gov/files/0b109485-1405-45b3-9cc4-0e68b0844c1a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 70; copy number 1: 21,443; copy number 2: 32,782; copy number 3: 3,610; copy number 4: 921; copy number 5: 47; copy number 8: 11; copy number 12: 9.

Homozygous deletions (total copy number 0; autosomes only): 63 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–71,585, 2 genes: OR4G11P, OR4F5.
- chr1:89,551–91,105, 1 gene (within-gene range 0–2): AL627309.3.
- chr1:629,062–634,922, 8 genes (within-gene range 0–1): MTND1P23, MTND2P28, MTCO1P12, AC114498.2, MTCO2P12, MTATP8P1, MTATP6P1, MTCO3P12.
- chr7:56,805,336–56,808,148, 1 gene: CICP28.
- chr7:76,959,835–77,043,775, 1 gene (within-gene range 0–2): DTX2P1-UPK3BP1-PMS2P11.
- chr7:76,978,617–77,032,361, 5 genes (within-gene range 0–2): DTX2P1, UPK3BP1, PMS2P11, Y_RNA, SPDYE17.
- chr7:102,433,106–102,473,168, 5 genes (within-gene range 0–2): ORAI2, ALKBH4, LRWD1, MIR5090, MIR4467.
- chr13:32,877,431–32,911,650, 1 gene: LINC00423.
- chr13:113,977,783–114,132,623, 2 genes (within-gene range 0–2): RASA3, RASA3-IT1.
- chr15:65,530,418–65,578,349, 2 genes: HACD3, RNU6-19P.
- chr15:75,724,041–75,738,623, 2 genes (within-gene range 0–1): ODF3L1, DNM1P35.
- chr15:90,902,218–90,955,225, 5 genes (within-gene range 0–1): MAN2A2, AC068831.3, HDDC3, UNC45A, RCCD1-AS1.
- chr16:1,206,560–1,207,124, 1 gene (within-gene range 0–2): AC120498.6.
- chr17:142,789–511,347, 11 genes (within-gene range 0–1): DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1, AC129507.2, AC129507.3, AC141424.1, C17orf97, RFLNB, AC015853.2.
- chr17:18,950,345–19,062,669, 7 genes: SLC5A10, AC090286.1, FAM83G, AC090286.4, GRAP, AC003957.1, SNORD3B-1.
- chr17:39,603,536–39,670,475, 6 genes: NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT.
- chr17:63,454,993–63,498,380, 3 genes (within-gene range 0–2): AC005828.5, PPIAP55, ACE.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 67 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:81,208,193–89,482,134, 54 genes, copy number 5–8: AC099542.2, AC099542.1, AC107302.2, AC107302.1, GBE1, RNU2-28P, SETP6, AC017015.1, AC017015.2, AC129807.1, LINC02008, RPL7AP23, CYP51A1P1, SRRM1P2, LINC00971, AC117482.1, LINC02025, CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1.
- chr18:30,713,275–30,714,286, 1 gene, copy number 5: AC090506.1.
- chr18:31,498,177–31,760,880, 9 genes, copy number 12: DSG2, DSG2-AS1, TTR, B4GALT6, AC017100.1, RN7SKP44, LRRC37A7P, AC017100.2, SLC25A52.
- chr18:31,962,178–31,986,087, 3 genes, copy number 8: PGDP1, AC009831.2, AC009831.4.

Autosomal genes at a single copy (total copy number 1): 18,793. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
